Somatic mutation profile of tumor specimen ALCH-B2AX-TTP1-A (aliquot ALCH-B2AX-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2AX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 41.6 years (15,180 days).
Specimen ALCH-B2AX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f85ba4b-671a-4645-8ab6-745d8256c6e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AX-NB1-A (Blood Derived Normal), aliquot ALCH-B2AX-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9adaa882-52a1-4b6a-8dc9-30168962602e

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 39/327 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.653T>G p.V218G | Missense Mutation (SNP) | VAF 35/173 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555525743, COSV52690974, COSV52712839, COSV52761003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPB1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.13); catalogued as rs756976312, COSV51572321, COSV51577486; called by muse, mutect2
- JPH2 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV65904321; called by mutect2, varscan2
- MFN2 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as rs375480365; ClinVar: uncertain significance; called by muse, mutect2
- NID2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs151032833; called by muse, mutect2, varscan2
- WFDC8 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.514); catalogued as rs377581195, COSV51489818; called by muse, mutect2
- APBB1IP | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CNTNAP1 | c.3361C>G p.R1121G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- ETNK2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- MVP | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NCAM2 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR2M2 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); called by muse, mutect2
- RELN | c.5902G>A p.D1968N | Missense Mutation (SNP) | VAF 10/328 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.071); called by muse, mutect2
- RELN | c.4923C>G p.F1641L | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- TACC2 | c.5669G>T p.G1890V (on ENST00000334433; = p.G81V on NM_206861.3) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IGKV3OR2-268 | c.27C>T p.F9= | Silent (SNP) | VAF 26/372 reads (7%) | called by muse, mutect2
- LRRIQ4 | c.354C>T p.H118= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs776478957, COSV61618617; called by muse, mutect2, varscan2
- PHF21B | c.879G>A p.L293= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- FMO6P | n.1826G>T | RNA (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- MOG | c.731-18A>G | Intron (SNP) | VAF 33/222 reads (15%) | catalogued as rs776123288; called by muse, mutect2, varscan2
